Somatic mutation profile of tumor specimen 0DP6I6 from CCDI case PBCDHU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.6 years (5,706 days).
Specimen 0DP6I6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd1a5bd0-f1f5-4a73-bf58-0ac40e872558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ca91315-4985-4517-a8ba-a5f54f15fb0b

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MROH8 | c.628A>G p.N210D | Missense Mutation (SNP) | VAF 335/849 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FGF13 | c.218-30321G>A | Intron (SNP) | VAF 63/198 reads (32%) | catalogued as rs753712009, COSV59543165; called by muse, mutect2, varscan2
- SLC22A17 | n.1317C>T | RNA (SNP) | VAF 32/452 reads (7%) | called by muse, mutect2
